Surgical pathology report (de-identified scan), TCGA case TCGA-AR-A2LE, project TCGA-BRCA (Breast Invasive Carcinoma), tissue source site Mayo, specimen TCGA-AR-A2LE-01A (Primary Tumor).

ICD 0-3
carcinoma, infiltrating lobular, NOS 8520/3
Site: breast, NOS C50.9
pw
8/17/11

Final Diagnosis

Breast, right, excision: Infiltrating lobular carcinoma, Nottingham I (of III) forming a 1.6 x 1.5 x 1.3 cm mass (AJCC pT1c). The carcinoma shows ductular involvement. No angiolymphatic involvement is present. The surgical resection margins, including the separately submitted margins, are negative for tumor.

Lymph nodes, right sentinel, excision: Negative for tumor.
Immunohistochemical cytokeratin stain was performed on the paraffin embedded sentinel lymph node tissue and confirms the H&E impression.

The infiltrating breast carcinoma is positive for estrogen receptor and negative for progesterone receptor.

Source: NCI Genomic Data Commons file 013643d8-723f-48a9-a315-0f7c6f766c58 (TCGA-AR-A2LE.95DC80AB-C070-4613-8C11-A124AEDF9754.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).